Somatic mutation profile of tumor specimen 0DTUXA from CCDI case PBCIZW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (1,003 days).
Specimen 0DTUXA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68c7eb0f-22cb-4413-af1e-cea90290ea70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUX2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c765872-0b1c-455f-aaab-afd4d125f70a

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 2, 3'UTR 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CANT1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 83/1142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766796841; called by muse, mutect2
- CHST5 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 80/643 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.771); catalogued as rs1212274563, COSV100291760; called by muse, mutect2, varscan2
- RIOK1 | c.1694A>G p.K565R | Missense Mutation (SNP) | VAF 124/1416 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); catalogued as rs746757404; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 75/1970 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- MROH6 | c.1634A>T p.D545V | Missense Mutation (SNP) | VAF 316/618 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- MUC12 | c.12375C>G p.D4125E (on ENST00000379442; = p.D3982E on NM_001164462.1) | Missense Mutation (SNP) | VAF 76/2098 reads (4%) | SIFT tolerated (0.58); called by muse, mutect2
- PCDH7 | c.2185T>C p.S729P | Missense Mutation (SNP) | VAF 146/1524 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SEC24B | c.3451G>A p.E1151K | Missense Mutation (SNP) | VAF 204/2658 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2
- UBP1 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 551/1444 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BRF1 | c.1378-11T>C | Intron (SNP) | VAF 940/1904 reads (49%) | called by muse, mutect2, varscan2
- CCK | c.*62G>T | 3'UTR (SNP) | VAF 68/1011 reads (7%) | called by muse, mutect2
- GNB3 | c.-3G>A | 5'UTR (SNP) | VAF 180/610 reads (30%) | called by muse, mutect2, varscan2
- NPR3 | chr5:32710710 G>C | 5'Flank (SNP) | VAF 688/1519 reads (45%) | called by muse, mutect2, varscan2
- RIMS1 | c.1679-20750C>T | Intron (SNP) | VAF 11/113 reads (10%) | catalogued as rs1019285760, COSV53488096; called by mutect2, varscan2
